MMRF case MMRF_1614 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e5fed665-34ef-4df0-b5d8-4a45a001b7fb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,144 days); ISS stage: II; Days to last known disease status: 1,094 days (3.0 years); Days to last follow up: 1,094 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 394 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,094.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 3): M Protein 2.9 g/dL; Immunoglobulin G 38.5 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.67 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.2 mmol/L; Calcium 2.36 mmol/L; Albumin 37 g/L; Total Protein 9.8 g/dL; Glucose 7.8 mmol/L.
- Day 84 (ECOG 3): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.19 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 9.3 mmol/L.
- Day 176 (ECOG 3): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Beta 2 Microglobulin 2.71 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.5 mmol/L; Calcium 2.24 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 8.6 mmol/L.
- Day 252 (ECOG 3): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Lactate Dehydrogenase 1.63 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 7.4 mmol/L.
- Day 373 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Beta 2 Microglobulin 2.49 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 65 µmol/L; Blood Urea Nitrogen 3.6 mmol/L; Calcium 2.16 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 11.2 mmol/L.
- Day 457 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 3.8 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 11.2 mmol/L.
- Day 518 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.21 mmol/L; Albumin 13 g/L; Total Protein 6.6 g/dL; Glucose 5.9 mmol/L.
- Day 623: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Beta 2 Microglobulin 2.82 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 83 µmol/L; Blood Urea Nitrogen 6.9 mmol/L; Calcium 2.24 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL.
- Day 707: M Protein 0 g/dL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 85 µmol/L; Blood Urea Nitrogen 6.7 mmol/L; Calcium 2.27 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.
- Day 799: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 81 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.26 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 8.2 mmol/L.
- Day 891 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 79 µmol/L; Blood Urea Nitrogen 6.8 mmol/L; Calcium 2.36 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 12.1 mmol/L.
- Day 1,064: Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 4.2 mmol/L; Calcium 2.16 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 8.7 mmol/L.

Other clinical attributes
- Day -4: Weight: 80 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1614_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1614_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
